Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WW, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WW-01A (Primary Tumor).

Gross:

Left adrenal gland with tumor (dimensions 80x50x50 mm, weight 39 g). On cut, thinly fibrously encapsulated grey-pink soft tumor.

Micro:

Pheochromocytoma solidly alveolarly a trabecularly shaped tumor with profound fibrotization (trichrom positive, congo and saturn red negative) and with adrenal cortex rests with pressure atrophy on surface; in some parts, tumor invades under the fibrous adrenal capsule, no infiltration behind the capsule was found. In the periadrenal fat tissue, large foci of Feyrter's metaplasia were found. Sustentacular cells (S100+) were found only sporadically, in large tumor parts are missed. Proliferation activity (MIB1) 1-2%.

PASS

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism

Nuclear hyperchromasia 1

Total 3

Procurement date:

Confirmation date:

ICD-O-3
Pheochromocytoma NOS
8700/0
Site ① Adrenal gland NOS
C74.9
JW 10/9/13

Source: NCI Genomic Data Commons file 8dcb11c6-7946-46db-a3db-e698487c4a88 (TCGA-S7-A7WW.F1EB47D2-F1B1-4D33-AA8B-5B3D13405AC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).